Somatic mutation profile of tumor specimen MMRF_1715_1_BM_CD138pos (aliquot MMRF_1715_1_BM_CD138pos_T1_KBS5U_L04824) from MMRF case MMRF_1715, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.7 years (20,723 days).
Specimen MMRF_1715_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8eec6335-0a8b-4fbc-ad34-f94ad086a165.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1715_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1715_1_PB_CD3pos_C3_KBS5U_L04836; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d969401-c7cb-46bf-90c8-a8fde1d7f901

The open-access MAF lists 263 somatic variants for this specimen: 90 protein-altering or splice-affecting, 36 silent, 137 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 73, Missense Mutation 72, Intron 37, Silent 36, Nonsense Mutation 12, 5'UTR 10, 5'Flank 9, RNA 4, 3'Flank 4, Splice Region 4, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.3742C>T p.Q1248* | Nonsense Mutation (SNP) | VAF 77/85 reads (91%) | catalogued as rs1569562936, CM098404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.2578A>G p.N860D (on ENST00000506720 / NM_001322402.2; = p.N792D on NM_015236.6) | Missense Mutation (SNP) | VAF 108/222 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); catalogued as COSV72229077; called by muse, mutect2, varscan2
- AFAP1L1 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 61/109 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs755876664, COSV57044011; called by muse, mutect2, varscan2
- BPIFB1 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 51/125 reads (41%) | catalogued as COSV99487554; called by muse, mutect2, varscan2
- CABYR | c.1172C>G p.S391C | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV100509981; called by muse, mutect2
- CD177 | c.1181A>G p.E394G | Missense Mutation (SNP) | VAF 143/324 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1479266404; called by muse, mutect2, varscan2
- CLCA4 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 85/106 reads (80%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as rs375888433; called by muse, mutect2, varscan2
- CNKSR2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as rs771705122, COSV54255339; called by muse, mutect2, varscan2
- CSH1 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 108/229 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs199753389; called by muse, mutect2, varscan2
- CST9L | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.228); catalogued as rs1213026066; called by muse, mutect2
- CYP2C19 | c.1150-1G>A p.X384_splice | Splice Site (SNP) | VAF 122/260 reads (47%) | catalogued as COSV64909675; called by muse, mutect2, varscan2
- EYS | c.2801C>T p.S934F | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV65527843; called by muse, mutect2
- FAM120C | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV60259001; called by muse, mutect2, varscan2
- FZD10 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 106/258 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1439601423, COSV57472000; called by muse, mutect2, varscan2
- IGHV2-70 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 63/66 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs576362735; called by muse, mutect2, varscan2
- LRP1B | c.7355G>A p.G2452E | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868321938; called by muse, mutect2, varscan2
- MAML3 | c.987C>A p.F329L | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59077288; called by muse, mutect2
- MBOAT1 | c.231C>G p.I77M | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV61126913, COSV61128017; called by muse, mutect2, varscan2
- MMP16 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV54153155; called by muse, mutect2, varscan2
- NF1 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 3/50 reads (6%) | catalogued as CD086493, COSV62224033; called by muse, mutect2
- NMT2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 135/323 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV65383193; called by muse, mutect2, varscan2
- NOTCH1 | c.3322C>A p.Q1108K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.08); catalogued as COSV53094612; called by muse, mutect2
- OR56A3 | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV61569771; called by muse, mutect2
- PCDHA9 | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.223); catalogued as rs782628181, COSV65329248; called by muse, mutect2, varscan2
- PREX1 | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64252720; called by muse, mutect2, varscan2
- QKI | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV51693669; called by muse, mutect2, varscan2
- RAP2A | c.117C>G p.F39L | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV55355069; called by muse, mutect2
- RIN2 | c.2671G>A p.E891K (on ENST00000255006 / NM_001242581.1; = p.E842K on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as rs777247848; called by muse, mutect2, varscan2
- RTN1 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as COSV50722883; called by muse, mutect2, varscan2
- RYR1 | c.12382G>A p.A4128T | Missense Mutation (SNP) | VAF 77/165 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.047); catalogued as COSV62094976; called by muse, mutect2, varscan2
- SLC6A5 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.77); catalogued as rs147809509; called by muse, mutect2, varscan2
- SND1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs772460220, COSV61250466; called by muse, varscan2
- SRRT | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 130/246 reads (53%) | catalogued as COSV100730292; called by muse, mutect2, varscan2
- TAF3 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 106/211 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV60208352; called by muse, mutect2, varscan2
- TRPC1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 83/214 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs971022230, COSV56423982; called by muse, mutect2, varscan2
- UBIAD1 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs1391520599; called by muse, mutect2
- ZNF333 | c.1855C>T p.Q619* | Nonsense Mutation (SNP) | VAF 43/134 reads (32%) | catalogued as COSV52886031; called by muse, mutect2, varscan2
- ZNF347 | c.2366G>A p.G789E | Missense Mutation (SNP) | VAF 15/274 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as COSV61967746; called by muse, mutect2
- ZNF446 | c.532+3G>A | Splice Region (SNP) | VAF 8/62 reads (13%) | catalogued as rs200650373; called by muse, mutect2
- ADAD2 | c.735G>A p.E245= (on ENST00000315906 / NM_001145400.2; = p.E327= on NM_139174.4) | Splice Region (SNP) | VAF 34/52 reads (65%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 67/190 reads (35%) | called by muse, mutect2, varscan2
- ARPP21 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ASPM | c.10209C>G p.Y3403* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- ATRX | c.1804G>T p.G602C | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2
- CCDC168 | c.12065C>G p.S4022C | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2
- CCDC7 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CEP83 | c.2080G>C p.E694Q | Missense Mutation (SNP) | VAF 23/538 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.329); called by muse, mutect2
- COX18 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSK | c.242+3G>C | Splice Region (SNP) | VAF 29/65 reads (45%) | called by muse, varscan2
- DBR1 | c.45G>T p.K15N | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- DGKI | c.690C>G p.F230L | Missense Mutation (SNP) | VAF 6/189 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.873); called by muse, mutect2
- EIF4G3 | c.4738G>A p.E1580K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ESCO2 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- FARP1 | c.21G>T p.R7S | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HIPK2 | c.2192C>A p.S731* | Nonsense Mutation (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- ILF3 | c.2534C>T p.S845L | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KRT75 | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- MAP10 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 74/300 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- MORF4L1 | c.625G>C p.D209H (on ENST00000331268 / NM_206839.2; = p.D170H on NM_006791.4) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MTFMT | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NAP1L1 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- NEMF | c.3132A>C p.K1044N | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- OR10A3 | c.186C>A p.F62L | Missense Mutation (SNP) | VAF 118/268 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PACS2 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PDE12 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.305); called by muse, mutect2
- PHF3 | c.4168G>A p.E1390K | Missense Mutation (SNP) | VAF 93/279 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PKD1L1 | c.4902G>C p.Q1634H | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- PLD4 | c.235G>C p.A79P | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- PLEKHA5 | c.3236G>C p.R1079T | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- PNISR | c.2156G>C p.R719T | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- POLDIP3 | c.1013_1021+7del p.X338_splice | Splice Site (DEL) | VAF 33/123 reads (27%) | called by mutect2, pindel, varscan2
- PTGR1 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 68/180 reads (38%) | called by mutect2, varscan2
- QSOX2 | c.705C>G p.S235R | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RP1 | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 64/152 reads (42%) | called by muse, mutect2, varscan2
- SAXO1 | c.871C>G p.P291A | Missense Mutation (SNP) | VAF 140/327 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- SDF4 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.139); called by mutect2, varscan2
- SLAIN2 | c.386G>A p.S129N | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC7A7 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.948); called by muse, mutect2
- STARD8 | c.1358G>A p.S453N | Missense Mutation (SNP) | VAF 100/125 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- TBC1D23 | c.1579G>C p.D527H | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); called by muse, mutect2
- TLCD5 | c.226C>A p.H76N (on ENST00000375095 / NM_001198671.2; = p.H98N on NM_174926.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.079); called by muse, mutect2
- TMEM159 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM237 | c.187G>A p.E63K (on ENST00000409883 / NM_001044385.3; = p.E55K on NM_152388.4) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- TOMM7 | c.128G>C p.G43A | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.591); called by muse, mutect2
- TP53I13 | c.1069+3G>A | Splice Region (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- TRAV17 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, mutect2
- TTC28 | c.6567G>C p.K2189N | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2
- USP15 | c.1736G>C p.S579T (on ENST00000280377 / NM_001351159.2; = p.S550T on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/234 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZFP92 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.339); called by muse, mutect2
- ZNF93 | c.1061C>G p.S354* | Nonsense Mutation (SNP) | VAF 78/290 reads (27%) | called by muse, mutect2, varscan2
- ADGRB2 | c.867G>T p.V289= | Silent (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- APOLD1 | c.402C>T p.I134= (on ENST00000326765 / NM_001130415.2; = p.I103= on NM_030817.3) | Silent (SNP) | VAF 40/83 reads (48%) | called by muse, mutect2, varscan2
- CACNA1I | c.3909C>G p.L1303= | Silent (SNP) | VAF 8/219 reads (4%) | called by muse, mutect2
- CD1D | c.873C>T p.I291= | Silent (SNP) | VAF 111/185 reads (60%) | catalogued as COSV63808977; called by muse, mutect2, varscan2
- CFAP206 | c.768A>G p.E256= | Silent (SNP) | VAF 59/112 reads (53%) | called by muse, mutect2, varscan2
- CPO | c.213G>A p.V71= | Silent (SNP) | VAF 57/147 reads (39%) | called by muse, mutect2, varscan2
- GASK1A | c.174C>A p.T58= | Silent (SNP) | VAF 59/113 reads (52%) | called by muse, mutect2, varscan2
- GTSE1 | c.1992C>T p.L664= | Silent (SNP) | VAF 73/158 reads (46%) | called by muse, mutect2, varscan2
- HRH1 | c.445C>T p.L149= | Silent (SNP) | VAF 12/192 reads (6%) | catalogued as COSV67955701, COSV67955944; called by muse, mutect2
- LACTB2 | c.795G>A p.L265= | Silent (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- LRPAP1 | c.996G>A p.K332= | Silent (SNP) | VAF 36/64 reads (56%) | called by muse, varscan2
- LRRC39 | c.303C>T p.F101= | Silent (SNP) | VAF 8/153 reads (5%) | called by muse, mutect2
- MAGI1 | c.1188G>A p.R396= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as rs768041548; called by muse, mutect2, varscan2
- MED12L | c.4818G>A p.L1606= | Silent (SNP) | VAF 153/314 reads (49%) | called by muse, mutect2, varscan2
- MUC5B | c.14379G>A p.L4793= | Silent (SNP) | VAF 12/342 reads (4%) | called by muse, mutect2
- MYH7B | c.4035G>C p.L1345= | Silent (SNP) | VAF 55/144 reads (38%) | catalogued as rs752405628; called by muse, mutect2, varscan2
- NDST4 | c.195G>A p.L65= | Silent (SNP) | VAF 111/234 reads (47%) | catalogued as rs996424865, COSV52118004; called by muse, mutect2, varscan2
- NODAL | c.948G>A p.V316= | Silent (SNP) | VAF 53/114 reads (46%) | called by muse, mutect2, varscan2
- NTN5 | c.279T>A p.S93= | Silent (SNP) | VAF 49/86 reads (57%) | called by muse, mutect2, varscan2
- OR52A5 | c.762C>T p.F254= | Silent (SNP) | VAF 21/526 reads (4%) | called by muse, mutect2
- OTP | c.393C>T p.I131= | Silent (SNP) | VAF 14/196 reads (7%) | catalogued as rs776968616, COSV60569997; called by muse, mutect2
- PHLDB2 | c.3126G>A p.L1042= (on ENST00000393925 / NM_001134439.2; = p.L999= on NM_145753.2) | Silent (SNP) | VAF 12/280 reads (4%) | catalogued as COSV67310054; called by muse, mutect2
- PPP5C | c.189C>T p.I63= | Silent (SNP) | VAF 12/256 reads (5%) | called by muse, mutect2
- RANBP17 | c.2652G>T p.L884= | Silent (SNP) | VAF 12/306 reads (4%) | called by muse, mutect2
- RNF130 | c.372C>T p.F124= | Silent (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- RSPO4 | c.573C>A p.P191= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- RUFY2 | c.1770C>G p.L590= | Silent (SNP) | VAF 27/195 reads (14%) | called by muse, mutect2, varscan2
- SFMBT1 | c.945T>C p.P315= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs770777692; called by mutect2, varscan2
- SH3KBP1 | c.1977G>A p.K659= | Silent (SNP) | VAF 104/137 reads (76%) | catalogued as COSV65648495; called by muse, mutect2, varscan2
- SHPK | c.144C>T p.V48= | Silent (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2
- SYNE2 | c.19329G>A p.L6443= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs1473579256; called by muse, mutect2, varscan2
- TEX15 | c.1860G>A p.Q620= (on ENST00000256246; = p.Q1003= on NM_001350162.2) | Silent (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- UTP20 | c.6984C>T p.I2328= | Silent (SNP) | VAF 8/209 reads (4%) | called by muse, mutect2
- VARS1 | c.2847C>T p.F949= | Silent (SNP) | VAF 12/275 reads (4%) | called by muse, mutect2
- ZMAT1 | c.1689G>A p.K563= | Silent (SNP) | VAF 8/209 reads (4%) | catalogued as COSV65658685; called by muse, mutect2
- ZNF445 | c.2817G>A p.L939= | Silent (SNP) | VAF 62/125 reads (50%) | catalogued as COSV101253739; called by muse, varscan2
- ABHD2 | c.*3235C>G | 3'UTR (SNP) | VAF 6/162 reads (4%) | called by muse, mutect2
- AC005863.1 | n.10G>A | RNA (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- AC093802.1 | n.1914+8147A>G | Intron (SNP) | VAF 57/167 reads (34%) | called by muse, mutect2, varscan2
- ACACA | c.*157G>A | 3'UTR (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- ADGB | c.3862+1314G>A | Intron (SNP) | VAF 51/94 reads (54%) | called by muse, mutect2, varscan2
- AGA | c.-37G>A | 5'UTR (SNP) | VAF 53/168 reads (32%) | called by muse, mutect2, varscan2
- ALG10B | c.*2918C>G | 3'UTR (SNP) | VAF 73/143 reads (51%) | called by muse, mutect2, varscan2
- AMD1 | c.*1739G>T | 3'UTR (SNP) | VAF 4/89 reads (4%) | called by muse, mutect2
- APOE | c.-24+44C>G | Intron (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.*342G>A | 3'UTR (SNP) | VAF 66/141 reads (47%) | called by muse, mutect2, varscan2
- ASF1A | c.*922G>A | 3'UTR (SNP) | VAF 83/157 reads (53%) | catalogued as rs1030174209; called by muse, mutect2, varscan2
- B3GNT4 | c.*257C>T | 3'UTR (SNP) | VAF 8/141 reads (6%) | called by muse, mutect2
- B4GALT6 | c.*156C>T | 3'UTR (SNP) | VAF 52/120 reads (43%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021570 C>T | 5'Flank (SNP) | VAF 28/65 reads (43%) | catalogued as rs551915100, COSV55848051; called by muse, mutect2, varscan2
- BEST1 | c.1739+534C>T | Intron (SNP) | VAF 7/138 reads (5%) | called by muse, mutect2
- BMP6 | c.*1140C>T | 3'UTR (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- BOLL | chr2:197786382 C>T | 5'Flank (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- BRD9 | c.966+98C>T | Intron (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- BRWD1 | c.6571+3121G>A | Intron (SNP) | VAF 11/193 reads (6%) | catalogued as rs1409882865; called by muse, mutect2
- CA13 | c.*280C>T | 3'UTR (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- CAMKK1 | c.685+82G>A | Intron (SNP) | VAF 48/83 reads (58%) | called by muse, mutect2, varscan2
- CCND3 | c.*328T>C | 3'UTR (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2
- CCT5 | c.*1297T>G | 3'UTR (SNP) | VAF 10/147 reads (7%) | called by muse, mutect2
- CENATAC | c.-19G>A | 5'UTR (SNP) | VAF 8/17 reads (47%) | catalogued as rs1247472902, COSV100548680; called by muse, mutect2, varscan2
- CFAP300 | c.111-48G>C | Intron (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*508C>T | 3'UTR (SNP) | VAF 83/236 reads (35%) | catalogued as rs553817755; called by muse, mutect2, varscan2
- CLEC16A | c.*2024C>G | 3'UTR (SNP) | VAF 7/64 reads (11%) | called by mutect2, varscan2
- CNST | c.*1331C>T | 3'UTR (SNP) | VAF 28/159 reads (18%) | called by muse, mutect2, varscan2
- COPS5 | c.*40G>A | 3'UTR (SNP) | VAF 12/400 reads (3%) | called by muse, mutect2
- CRTC2 | c.-62G>A | 5'UTR (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2
- CYP4F8 | c.343+336G>A | Intron (SNP) | VAF 94/130 reads (72%) | called by muse, varscan2
- DBF4B | c.1189+972A>G | Intron (SNP) | VAF 51/116 reads (44%) | called by muse, mutect2, varscan2
- DDB1 | c.1006-80C>G | Intron (SNP) | VAF 12/330 reads (4%) | called by muse, mutect2
- DHRS4L1 | n.177-401G>T | Intron (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- DIP2C | c.86-9C>G | Intron (SNP) | VAF 28/183 reads (15%) | called by muse, mutect2, varscan2
- DLGAP2 | c.*6408G>A | 3'UTR (SNP) | VAF 6/129 reads (5%) | catalogued as rs911744210, COSV70101294; called by muse, mutect2
- DNAH10 | c.11440+73G>C | Intron (SNP) | VAF 5/130 reads (4%) | called by muse, mutect2
- DNAJA4 | c.132+896G>C | Intron (SNP) | VAF 67/145 reads (46%) | called by muse, mutect2, varscan2
- DOCK4 | c.-226G>A | 5'UTR (SNP) | VAF 44/90 reads (49%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.8637+149G>T | Intron (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- ECHDC2 | chr1:52921759 G>A | 5'Flank (SNP) | VAF 56/135 reads (41%) | called by muse, mutect2, varscan2
- ELAVL4 | chr1:50202986 G>C | 3'Flank (SNP) | VAF 57/115 reads (50%) | called by muse, mutect2, varscan2
- ETS1 | chr11:128460099 C>A | 3'Flank (SNP) | VAF 5/32 reads (16%) | catalogued as rs774630781; called by muse, varscan2
- FAM110B | c.*1240C>G | 3'UTR (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- FAM162B | c.-135G>A | 5'UTR (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- FBRS | chr16:30659941 C>T | 5'Flank (SNP) | VAF 19/58 reads (33%) | catalogued as rs1316442136; called by muse, mutect2, varscan2
- GAB1 | chr4:143472968 G>C | 3'Flank (SNP) | VAF 14/98 reads (14%) | called by mutect2, varscan2
- GABRB2 | c.*1469T>A | 3'UTR (SNP) | VAF 65/144 reads (45%) | called by muse, mutect2, varscan2
- GALNT17 | c.*209G>A | 3'UTR (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- GATAD2B | c.*5333C>T | 3'UTR (SNP) | VAF 48/128 reads (38%) | called by muse, mutect2, varscan2
- GIGYF2 | c.1899-58C>T | Intron (SNP) | VAF 33/68 reads (49%) | called by muse, mutect2, varscan2
- GIPR | c.488+81C>T | Intron (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- GSTM3 | c.*1779G>A | 3'UTR (SNP) | VAF 59/60 reads (98%) | called by muse, mutect2, varscan2
- GUCY1B1 | c.*1026A>T | 3'UTR (SNP) | VAF 73/158 reads (46%) | called by muse, mutect2, varscan2
- H2BC21 | c.*840C>T | 3'UTR (SNP) | VAF 64/274 reads (23%) | called by muse, mutect2, varscan2
- HELLS | c.1326+1028G>A | Intron (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- HIPK2 | c.*7081C>G | 3'UTR (SNP) | VAF 20/32 reads (63%) | called by muse, mutect2, varscan2
- HOXD1 | c.*116G>A | 3'UTR (SNP) | VAF 9/158 reads (6%) | called by muse, mutect2
- HS1BP3 | c.623+735G>C | Intron (SNP) | VAF 61/146 reads (42%) | called by muse, mutect2, varscan2
- HS3ST3B1 | c.*1440T>A | 3'UTR (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- HS6ST2 | c.*1150C>A | 3'UTR (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- IL13 | c.*378C>T | 3'UTR (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- ING1 | chr13:110713740 G>A | 5'Flank (SNP) | VAF 75/90 reads (83%) | called by muse, mutect2, varscan2
- INO80D | c.*8799G>A | 3'UTR (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- IP6K2 | c.-26A>T | 5'UTR (SNP) | VAF 10/266 reads (4%) | called by muse, mutect2
- KCNH8 | c.*404C>G | 3'UTR (SNP) | VAF 37/88 reads (42%) | called by muse, mutect2, varscan2
- KCNJ11 | chr11:17388867 C>G | 5'Flank (SNP) | VAF 83/195 reads (43%) | called by muse, mutect2, varscan2
- KCNJ3 | c.*2608A>T | 3'UTR (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- KCNJ9 | c.*78A>T | 3'UTR (SNP) | VAF 4/48 reads (8%) | catalogued as rs1289820529, COSV58758158; called by muse, mutect2
- KMT5A | c.*1140C>T | 3'UTR (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- LGALS9 | chr17:27630273 C>T | 5'Flank (SNP) | VAF 10/199 reads (5%) | called by muse, mutect2
- LHX4 | c.*3078C>T | 3'UTR (SNP) | VAF 35/131 reads (27%) | called by muse, mutect2, varscan2
- LINC02870 | n.758G>A | RNA (SNP) | VAF 42/87 reads (48%) | called by muse, mutect2
- LRRC43 | chr12:122183039 C>T | 5'Flank (SNP) | VAF 46/86 reads (53%) | called by muse, mutect2
- LYN | c.*553T>C | 3'UTR (SNP) | VAF 13/228 reads (6%) | catalogued as rs1369630549; called by muse, mutect2
- MAGEA1 | c.-81A>G | 5'UTR (SNP) | VAF 90/114 reads (79%) | catalogued as COSV100756702; called by muse, mutect2, varscan2
- MASP1 | c.1090+3267C>G | Intron (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- MCHR1 | c.*766G>C | 3'UTR (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- MDS2 | n.211C>T | RNA (SNP) | VAF 13/220 reads (6%) | called by muse, mutect2
- METTL2B | c.*141G>A | 3'UTR (SNP) | VAF 62/154 reads (40%) | called by muse, mutect2, varscan2
- MIR518A1 | n.42G>A | RNA (SNP) | VAF 63/124 reads (51%) | catalogued as rs757686945; called by muse, mutect2, varscan2
- MTG2 | c.*965G>C | 3'UTR (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- MYCT1 | c.*969A>T | 3'UTR (SNP) | VAF 90/182 reads (49%) | called by muse, mutect2, varscan2
- MYO5A | c.*4909C>T | 3'UTR (SNP) | VAF 65/147 reads (44%) | catalogued as rs922429595; called by muse, mutect2, varscan2
- NAT2 | c.*129C>T | 3'UTR (SNP) | VAF 148/198 reads (75%) | catalogued as rs1263303601; called by muse, mutect2, varscan2
- NCKAP5 | c.341+6706C>G | Intron (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- NEXMIF | c.*6471G>A | 3'UTR (SNP) | VAF 16/24 reads (67%) | catalogued as rs1288092732; called by muse, mutect2, varscan2
- NFYC | c.*457C>T | 3'UTR (SNP) | VAF 9/243 reads (4%) | catalogued as rs939194800; called by muse, mutect2
- PAIP2B | c.*4502G>A | 3'UTR (SNP) | VAF 54/134 reads (40%) | called by muse, mutect2, varscan2
- PAPPA2 | c.*2810T>C | 3'UTR (SNP) | VAF 39/114 reads (34%) | called by muse, mutect2, varscan2
- PASK | c.3333+731C>T | Intron (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- PASK | c.3333+288C>T | Intron (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
- PDE4D | c.*2347C>G | 3'UTR (SNP) | VAF 52/119 reads (44%) | called by muse, mutect2, varscan2
- PDZK1IP1 | c.*15C>G | 3'UTR (SNP) | VAF 70/153 reads (46%) | called by muse, mutect2, varscan2
- PGAP4 | c.*1577G>A | 3'UTR (SNP) | VAF 66/154 reads (43%) | called by muse, mutect2, varscan2
- PHC3 | c.537+460G>A | Intron (SNP) | VAF 14/241 reads (6%) | called by muse, mutect2
- PIGK | c.*821C>T | 3'UTR (SNP) | VAF 8/149 reads (5%) | catalogued as rs1193450603; called by muse, mutect2
- PIM2 | c.-159C>G | 5'UTR (SNP) | VAF 4/61 reads (7%) | called by muse, mutect2
- PLA2G4F | c.*107C>G | 3'UTR (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- PNCK | c.538+80G>A | Intron (SNP) | VAF 88/98 reads (90%) | catalogued as rs1451185398; called by muse, varscan2
- PNPLA5 | c.*312C>T | 3'UTR (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- PRRG1 | c.*202G>C | 3'UTR (SNP) | VAF 38/146 reads (26%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.2239+107C>G | Intron (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- RHOBTB2 | c.*383G>T | 3'UTR (SNP) | VAF 7/128 reads (5%) | called by muse, mutect2
- RIN1 | c.1876-132C>T | Intron (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- RNF169 | c.*5172C>G | 3'UTR (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- SAA4 | c.*139C>T | 3'UTR (SNP) | VAF 41/86 reads (48%) | called by muse, mutect2, varscan2
- SEC62 | c.*4312C>T | 3'UTR (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- SEMA3G | c.*219C>T | 3'UTR (SNP) | VAF 53/108 reads (49%) | called by muse, mutect2, varscan2
- SETD7 | c.*429G>C | 3'UTR (SNP) | VAF 5/110 reads (5%) | called by muse, mutect2
- SETX | c.*2758G>C | 3'UTR (SNP) | VAF 62/128 reads (48%) | called by muse, mutect2, varscan2
- SGMS2 | chr4:107911727 C>T | 3'Flank (SNP) | VAF 8/178 reads (4%) | catalogued as rs977129625; called by muse, mutect2
- SHMT2 | c.33+31C>T | Intron (SNP) | VAF 175/345 reads (51%) | called by muse, mutect2, varscan2
- SLC29A1 | c.*118C>A | 3'UTR (SNP) | VAF 67/183 reads (37%) | called by muse, mutect2, varscan2
- SLC39A8 | c.*403C>T | 3'UTR (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- SMU1 | c.*3678C>T | 3'UTR (SNP) | VAF 6/139 reads (4%) | called by muse, mutect2
- SORBS2 | c.*589G>A | 3'UTR (SNP) | VAF 13/224 reads (6%) | called by muse, mutect2
- SP140 | c.406+56C>G | Intron (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- SSU72 | c.-52G>A | 5'UTR (SNP) | VAF 34/62 reads (55%) | called by muse, mutect2, varscan2
- SVIP | c.*2576G>A | 3'UTR (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- TET2 | c.*717C>T | 3'UTR (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- THAP2 | c.71+459G>C | Intron (SNP) | VAF 22/574 reads (4%) | catalogued as rs951986113; called by muse, mutect2
- TMEM132D | c.1444-291G>T | Intron (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- TMEM199 | c.211+220C>G | Intron (SNP) | VAF 43/101 reads (43%) | called by muse, mutect2, varscan2
- TRAFD1 | c.*709G>C | 3'UTR (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- TTC3 | c.*1137C>T | 3'UTR (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- TTN | c.93760+60A>T | Intron (SNP) | VAF 131/247 reads (53%) | called by muse, mutect2, varscan2
- U2SURP | c.-4C>T | 5'UTR (SNP) | VAF 56/132 reads (42%) | catalogued as COSV67530342; called by muse, mutect2, varscan2
- UNC5D | c.*845G>C | 3'UTR (SNP) | VAF 45/93 reads (48%) | called by muse, mutect2, varscan2
- UXT | chrX:47659905 C>T | 5'Flank (SNP) | VAF 7/139 reads (5%) | called by muse, mutect2
- WDFY3 | c.*2594G>A | 3'UTR (SNP) | VAF 5/114 reads (4%) | called by muse, mutect2
- WDR90 | c.11-148C>T | Intron (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2, varscan2
- XCL1 | c.*792C>T | 3'UTR (SNP) | VAF 56/200 reads (28%) | called by muse, mutect2, varscan2
- YAF2 | c.153-37469G>C | Intron (SNP) | VAF 13/180 reads (7%) | called by muse, mutect2
- ZNF215 | c.*21T>A | 3'UTR (SNP) | VAF 212/456 reads (46%) | called by muse, mutect2, varscan2
- ZNF528 | c.272-280C>T | Intron (SNP) | VAF 31/125 reads (25%) | called by muse, mutect2, varscan2
- ZNF785 | c.*90G>A | 3'UTR (SNP) | VAF 33/523 reads (6%) | called by muse, mutect2
